HCMI case HCM-BROD-0124-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/03bfeb7c-cecf-4691-8263-33cdfe391ea9

Demographics
Sex at birth: male; Race: white; Year of birth: 1955; Vital status: Dead; Days to death: 481 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Classification of tumor: primary; Age at diagnosis: 60.5 years (22,096 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 0; Peripancreatic lymph nodes tested: 2.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 252 days; Days to treatment end: 286 days.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 252 days; Days to treatment end: 290 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 359 days; Days to treatment end: 420 days (1.1 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Days to follow up: 478 days (1.3 years); Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- CA19-9: 87.
- CEA: 1.1; Blood test normal range upper: 4.1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Occasional Drinker; Alcohol days per week: 1.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-BROD-0124-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
- Sample HCM-BROD-0124-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-BROD-0124-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
